FM case AD5603 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/6fe2217c-84b7-405b-8d4d-eabbae8f4427

Female, 43.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the bladder; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
